Somatic mutation profile of tumor specimen MP2PRT-PAVYIF-TMP1-A (aliquot MP2PRT-PAVYIF-TMP1-A-1-0-D-A83C-36) from MP2PRT case MP2PRT-PAVYIF, project MP2PRT-ALL (Molecular Profiling to Predict Response to Treatment for Acute Lymphoblastic Leukemia). Sex at birth: male; Vital status: Alive; Primary diagnosis: Common precursor B ALL; Tissue or organ of origin: Bone marrow; Age at diagnosis: 3.5 years (1,281 days).
Specimen MP2PRT-PAVYIF-TMP1-A: Sample type: Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Whole Bone Marrow; Biospecimen anatomic site: Bone Marrow; Preservation method: Cryopreserved.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) f459e9e2-30f8-4b32-b9ee-cc50adb42295.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen MP2PRT-PAVYIF-NM1-A (Blood Derived Cancer - Bone Marrow, Post-treatment; tissue type Normal — post-treatment blood used as the germline comparator), aliquot MP2PRT-PAVYIF-NM1-A-1-0-D-A83C-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/8d3ae594-6c1f-4f1d-b761-a6229fcd6b95

The open-access MAF lists 20 somatic variants for this specimen: 18 protein-altering or splice-affecting, 2 silent.
By variant classification: Missense Mutation 15, Silent 2, Nonsense Mutation 1, Splice Site 1, Splice Region 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- KRAS | c.351A>T p.K117N | Missense Mutation (SNP) | VAF 99/321 reads (31%) | hotspot (GDC flag); SIFT deleterious (0.01); PolyPhen probably damaging (0.994); catalogued as rs770248150, COSV55504752, COSV55545304; ClinVar: pathogenic; called by muse, mutect2, varscan2
- ANKRD18B | c.3002G>A p.R1001H | Missense Mutation (SNP) | VAF 92/293 reads (31%) | SIFT tolerated, low confidence (0.15); PolyPhen benign (0.001); catalogued as rs561973679; called by muse, mutect2, varscan2
- AR | c.2440T>G p.F814V | Missense Mutation (SNP) | VAF 117/262 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (0.977); catalogued as COSV101017553, COSV65954499; called by muse, mutect2, varscan2
- CCDC85A | c.665C>T p.P222L | Missense Mutation (SNP) | VAF 214/625 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs752700528, COSV101339442, COSV68151326; called by muse, mutect2, varscan2
- CEACAM18 | c.590G>A p.R197H | Missense Mutation (SNP) | VAF 168/417 reads (40%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.93); catalogued as rs765039070; called by muse, mutect2, varscan2
- CHMP4B | c.609C>T p.P203= | Splice Region (SNP) | VAF 83/236 reads (35%) | catalogued as rs201373276; called by muse, mutect2, varscan2
- FOXO1 | c.640C>A p.R214S | Missense Mutation (SNP) | VAF 65/173 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as COSV65426118; called by muse, mutect2, varscan2
- LIMCH1 | c.565G>A p.D189N | Missense Mutation (SNP) | VAF 135/570 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as rs925258645, COSV58300436; called by muse, mutect2, varscan2
- NPTXR | c.943G>A p.E315K | Missense Mutation (SNP) | VAF 183/493 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs750717348; called by muse, mutect2, varscan2
- PRKD1 | c.1853G>A p.R618Q | Missense Mutation (SNP) | VAF 65/267 reads (24%) | SIFT deleterious (0); PolyPhen possibly damaging (0.736); catalogued as rs771285195; called by muse, mutect2, varscan2
- SSX7 | c.137T>A p.I46N | Missense Mutation (SNP) | VAF 81/98 reads (83%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs782261388; called by muse, mutect2, varscan2
- WHRN | c.725G>A p.R242H | Missense Mutation (SNP) | VAF 154/502 reads (31%) | SIFT deleterious (0.01); PolyPhen benign (0.168); catalogued as rs727505127; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- ANKRD55 | c.312+1G>A p.X104_splice | Splice Site (SNP) | VAF 83/222 reads (37%) | called by muse, mutect2, varscan2
- CCDC150 | c.2588G>A p.R863K | Missense Mutation (SNP) | VAF 18/423 reads (4%) | SIFT tolerated (0.51); PolyPhen benign (0.391); called by muse, mutect2
- DOK7 | c.407A>T p.D136V | Missense Mutation (SNP) | VAF 224/953 reads (24%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.948); called by mutect2, varscan2
- ITGA6 | c.1786C>T p.Q596* (on ENST00000442250; = p.Q557* on NM_000210.4 and 1 other RefSeq transcript) | Nonsense Mutation (SNP) | VAF 92/415 reads (22%) | called by muse, mutect2, varscan2
- PIK3R6 | c.1690A>G p.K564E | Missense Mutation (SNP) | VAF 118/350 reads (34%) | SIFT tolerated (0.45); PolyPhen benign (0.1); called by muse, mutect2, varscan2
- WDR49 | c.1712C>T p.T571I (on ENST00000308378 / NM_001366158.1; = p.T912I on NM_001348951.2 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 39/141 reads (28%) | SIFT tolerated (0.07); PolyPhen benign (0.024); called by muse, mutect2, varscan2
- ADAMTS17 | c.648G>A p.S216= | Silent (SNP) | VAF 179/536 reads (33%) | catalogued as rs779009930; called by muse, mutect2, varscan2
- RTEL1 | c.1963C>A p.R655= | Silent (SNP) | VAF 173/507 reads (34%) | called by muse, mutect2, varscan2
